Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A1Q1, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A1Q1-06A (Metastatic).

[page 1 of 2]
***** **MODIFIED REPORT - REVIEW ADDENDUM SECTION** *****

DIAGNOSIS

(A) RIGHT FEMORAL LYMPH NODE:

**SCAR AND METASTATIC MALIGNANT MELANOMA IN SUBCUTANEOUS TISSUE.
METASTATIC MALIGNANT MELANOMA IN TWO OF SIX LYMPH NODES (2/6)
THE LARGEST FOCUS IS 130.0 X 65.0 (LIKELY MATTED NODES)
TUMOR IS SUBCAPSULAR, INTRAPARENCHYMAL, WITH EXTRANODAL EXTENSION.**

(B) RIGHT ILIAC AND OBTURATOR LYMPH NODE:

ONE OF TWELVE LYMPH NODES WITH METASTATIC MALIGNANT MELANOMA (4.5 X 3.0 MM), SUBCAPSULAR AND INTRAPARENCHYMAL, WITH EXTRANODAL EXTENSION (1/12).

(C) AMPUTATION RIGHT GREAT TOE:

**Skin and soft tissue resection with scar.
Please see addendum report.**

(D) SUBCUTANEOUS MASS FIRST WEB SPACE RIGHT FOOT:

METASTATIC MALIGNANT MELANOMA IN DERMIS, BIOPSIED.

1CD-0-3
Melanoma, NOS 8720/3
Site: lymph node C17.9 lw 3/15/11

Entire report and diagnosis completed by

MD

HPA/AA Discrepancy		

COMMENT

(A) Immunohistochemical studies are performed on two sections. The tumor cells are pan-mel positive and negative for keratin, supporting the diagnosis.

GROSS DESCRIPTION

(A) **RIGHT FEMORAL LYMPH NODE** – A yellow-tan irregular fragment of fibroadipose tissue measuring 29 x 9 x 4.6 cm, is received with an attached white-tan irregular fragment of skin measuring 20.3 x 5 cm. The surface of the skin displays a healed scar measuring 5 cm in length. The specimen is sectioned and possible lymph nodes are found ranging in size from 0.4 x 0.4 x 0.3 cm to 3 x 1 x 0.5 cm. Also a grossly positive matted lymph node measuring 13 x 6.5 x 4.8 cm is found.

SECTION CODE: A1, representative section of skin with scar.; A2, two possible lymph nodes; A3, two possible lymph nodes; A4, one bisected possible lymph nodes; A5-A6, one serially sectioned possible lymph nodes; A7-A12, representative sections of the grossly positive matted lymph node.

(B) **RIGHT ILIAC AND OBTURATOR LYMPH NODE** - A yellow-tan irregular fragment of hemorrhagic adipose tissue (6.0 x 4.2 x 1.3 cm). The specimen is sectioned and twelve possible lymph nodes are found ranging in size from 0.6 x 0.5 x 0.3 cm to 3.0 x 1.8 x 0.6 cm.

SECTION CODE: B1, three possible lymph nodes; B2, three possible lymph nodes; B3, two possible lymph nodes; B4, two possible lymph nodes; B5, one possible lymph node; B6-B7, one bisected possible lymph node.

(C) **AMPUTATION RIGHT GREAT TOE** - A great toe (4.0 x 3.5 x 2.3 cm) is received amputated through the metatarsal bone. The toenail is present and is grossly unremarkable. There is a possible scar (0.8 cm in length) found on the medial aspect of the toe and is 0.5 cm from the nail bed. The bone and soft tissue at the resection margin are grossly unremarkable. The resection margin is inked in black and representative sections of the specimen are submitted.

SECTION CODE: C1, full-thickness section of nail bed, bone and skin adjacent to the scar. The section is sent to the bone lab for further processing; C2, bone and soft tissue at resection margin en face, sent to the bone lab for further processing; C3, scar; C4, soft tissue. Representative section of soft tissue at the resection margin.

Sample

[page 2 of 2]
(D) SUBCUTANEOUS MASS FIRST WEB SPACE RIGHT FOOT - A white-tan unoriented ellipse of skin (1.0 x 0.5 x 0.3 cm). the surface is grossly unremarkable. The specimen is inked in blue, serially sectioned and entirely submitted.

SECTION CODE D1, tip; D2, remainder of the specimen.

CLINICAL HISTORY

Melanoma.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by . These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Released by:

Start of

ADDENDUM

ADDENDUM

(C) Sections (C1 and C2) are examined following decalcification. No tumor is identified.

Released by: MD

-----END OF REPORT-----

REVISIONS

Source: NCI Genomic Data Commons file 2a3bf32b-806e-456e-8a7d-326563ddb450 (TCGA-D3-A1Q1.14A845B4-E16D-4BC3-9562-B077E9C363F3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).